MMRF case MMRF_1988 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d4444070-7705-4775-a720-12734dd88643

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.4 years (26,816 days); ISS stage: II; Days to last known disease status: 995 days (2.7 years); Days to last follow up: 995 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 115 days; Days to treatment end: 115 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -46 (ECOG 1): M Protein 3.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.1 mg/dL; Immunoglobulin G 51.9 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.58 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 34 g/L; Total Protein 9.7 g/dL; Glucose 5.72 mmol/L.
- Day 32 (ECOG 1): M Protein 1.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.74 mg/dL; Immunoglobulin G 33 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 32 g/L; Total Protein 7.8 g/dL; Glucose 5.39 mmol/L.
- Day 137 (ECOG 1): Lactate Dehydrogenase 10.2 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 6.66 mmol/L.
- Day 232 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 8.81 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 182 ×10⁹/L.
- Day 473 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 4.57 mmol/L.
- Day 568 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.
- Day 659 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL.
- Day 750 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 841 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 995 (ECOG 1): Hemoglobin 7.87 mmol/L; Leukocytes 13 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 211 ×10⁹/L.

Other clinical attributes
- Day -46: Weight: 54 kg; Height: 154 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1988_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -46 days.
- Sample MMRF_1988_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -46 days.
